Somatic mutation profile of tumor specimen MMRF_2524_1_BM_CD138pos (aliquot MMRF_2524_1_BM_CD138pos_T1_KHS5U_K15167) from MMRF case MMRF_2524, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 65.2 years (23,821 days).
Specimen MMRF_2524_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a61ac508-3223-4f8c-a646-e81790459ef6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2524_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2524_1_PB_Whole_C3_KHS5U_K15166; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b95b4826-9bde-4cda-b414-a5d20ba8c031

The open-access MAF lists 148 somatic variants for this specimen: 54 protein-altering or splice-affecting, 26 silent, 68 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 45, 3'UTR 32, Silent 26, Intron 22, 3'Flank 6, 5'UTR 6, Splice Site 3, 5'Flank 2, Nonsense Mutation 2, Frame Shift Del 1, Translation Start Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRCA1 | c.1961dup p.Y655Vfs*18 | Frame Shift Ins (INS) | VAF 103/180 reads (57%) | catalogued as rs80357522; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by mutect2, varscan2
- CATSPERG | c.854C>T p.S285F | Missense Mutation (SNP) | VAF 14/203 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1568375928; called by muse, mutect2
- DAPK3 | c.1234C>T p.R412C | Missense Mutation (SNP) | VAF 47/114 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.724); catalogued as rs769532059; called by muse, mutect2, varscan2
- FMO4 | c.235C>A p.P79T | Missense Mutation (SNP) | VAF 33/65 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63001643; called by muse, mutect2, varscan2
- IGHJ4 | c.22G>T p.G8* | Nonsense Mutation (SNP) | VAF 74/74 reads (100%) | catalogued as rs782661181; called by muse, varscan2
- IGLV3-1 | c.251A>G p.N84S | Missense Mutation (SNP) | VAF 48/50 reads (96%) | SIFT tolerated (0.45); PolyPhen benign (0.01); catalogued as rs373605544; called by muse, varscan2
- IGLV3-25 | c.268A>T p.T90S | Missense Mutation (SNP) | VAF 74/182 reads (41%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.955); catalogued as rs1249962859; called by muse, varscan2
- LAMA1 | c.6794T>G p.V2265G | Missense Mutation (SNP) | VAF 68/140 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.578); catalogued as COSV101054907; called by muse, mutect2, varscan2
- MUC16 | c.19354C>T p.H6452Y | Missense Mutation (SNP) | VAF 63/191 reads (33%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.03); catalogued as rs371417922; called by muse, mutect2, varscan2
- MYH13 | c.5629G>A p.A1877T | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as rs530814088; called by muse, mutect2, varscan2
- NOL9 | c.376C>G p.L126V | Missense Mutation (SNP) | VAF 10/14 reads (71%) | SIFT tolerated (0.36); PolyPhen benign (0.005); catalogued as rs1233758911, COSV100063294; called by muse, varscan2
- ORC1 | c.1586G>A p.C529Y | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65364685; called by muse, mutect2, varscan2
- SALL3 | c.1028C>T p.P343L | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.013); catalogued as rs1405689927, COSV73305717; called by muse, mutect2, varscan2
- SCP2 | c.1338G>C p.E446D | Missense Mutation (SNP) | VAF 36/86 reads (42%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV101027029; called by muse, mutect2, varscan2
- TACR1 | c.302G>A p.G101D | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs763443404; called by muse, mutect2, varscan2
- TNR | c.991G>A p.D331N | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT tolerated (0.7); PolyPhen benign (0.015); catalogued as COSV99691099; called by muse, mutect2, varscan2
- AKT1 | c.180C>A p.C60* | Nonsense Mutation (SNP) | VAF 31/98 reads (32%) | called by muse, mutect2, varscan2
- ALK | c.1478C>T p.T493I | Missense Mutation (SNP) | VAF 27/48 reads (56%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- ATP2B1 | c.862T>C p.F288L | Missense Mutation (SNP) | VAF 28/310 reads (9%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.979); called by muse, mutect2
- BAZ1B | c.2278T>G p.Y760D | Missense Mutation (SNP) | VAF 68/183 reads (37%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- C3orf18 | c.170C>A p.A57D | Missense Mutation (SNP) | VAF 95/150 reads (63%) | SIFT tolerated (0.14); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- COLQ | c.237G>A p.M79I | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2
- EHD1 | c.373C>G p.L125V | Missense Mutation (SNP) | VAF 36/68 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- EPHA5 | c.1856G>T p.W619L | Missense Mutation (SNP) | VAF 5/78 reads (6%) | SIFT tolerated (0.65); PolyPhen benign (0); called by muse, mutect2
- FAM47B | c.1435A>T p.I479F | Missense Mutation (SNP) | VAF 87/92 reads (95%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- FOXO1 | c.615C>G p.S205R | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- GULP1 | c.448A>T p.R150W | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- KANK2 | c.191T>C p.V64A | Missense Mutation (SNP) | VAF 42/192 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.314); called by muse, mutect2, varscan2
- KCNA7 | c.295G>C p.G99R | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- KMT2E | c.1887+2T>C p.X629_splice | Splice Site (SNP) | VAF 17/55 reads (31%) | called by muse, mutect2, varscan2
- LCORL | c.5315C>A p.T1772N | Missense Mutation (SNP) | VAF 39/77 reads (51%) | SIFT tolerated (0.17); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- MAB21L4 | c.1291G>T p.A431S (on ENST00000388934 / NM_001085437.3; = p.A263S on NM_024861.4) | Missense Mutation (SNP) | VAF 51/107 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.187); called by muse, mutect2, varscan2
- MALRD1 | c.236T>A p.L79H | Missense Mutation (SNP) | VAF 42/85 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- MAMSTR | c.680G>A p.R227H (on ENST00000318083 / NM_001130915.2; = p.R124H on NM_182574.2) | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); called by muse, mutect2
- MST1 | c.766A>C p.N256H | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- OR10H3 | c.941T>C p.L314P | Missense Mutation (SNP) | VAF 91/129 reads (71%) | SIFT deleterious (0.04); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- OR5A2 | c.740C>T p.T247I | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- PAQR9 | c.842A>G p.Y281C | Missense Mutation (SNP) | VAF 17/262 reads (6%) | SIFT tolerated (0.21); PolyPhen benign (0.066); called by muse, mutect2
- PCARE | c.3330del p.V1111Sfs*2 | Frame Shift Del (DEL) | VAF 60/149 reads (40%) | called by mutect2, pindel, varscan2
- PCDH15 | c.2839A>G p.T947A | Missense Mutation (SNP) | VAF 154/340 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.262); called by muse, mutect2, varscan2
- PPIG | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 65/147 reads (44%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- PRKCD | c.1965G>A p.M655I | Missense Mutation (SNP) | VAF 38/468 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.061); called by muse, mutect2
- PRKDC | c.4271C>A p.T1424K | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- PSMA4 | c.3+2T>A p.X1_splice | Splice Site (SNP) | VAF 75/294 reads (26%) | called by muse, mutect2, varscan2
- REV1 | c.54+1G>A p.X18_splice | Splice Site (SNP) | VAF 117/282 reads (41%) | called by muse, mutect2, varscan2
- RNF19B | c.1025G>A p.S342N | Missense Mutation (SNP) | VAF 7/90 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); called by muse, mutect2
- RNH1 | c.1249C>A p.Q417K | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.061); called by muse, mutect2
- SDSL | c.262A>G p.I88V | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT tolerated (0.57); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SLC4A10 | c.2250A>T p.R750S (on ENST00000446997 / NM_001354461.2; = p.R720S on NM_022058.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 58/131 reads (44%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- SSTR1 | c.620C>T p.A207V | Missense Mutation (SNP) | VAF 27/209 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- ZNF157 | c.297A>C p.G99= | Splice Region (SNP) | VAF 25/28 reads (89%) | called by muse, varscan2
- ZNF606 | c.230G>T p.G77V | Missense Mutation (SNP) | VAF 34/114 reads (30%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.481); called by muse, mutect2, varscan2
- ZNF862 | c.2861C>T p.A954V | Missense Mutation (SNP) | VAF 11/157 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.005); called by muse, mutect2
- ZSWIM5 | c.334T>C p.Y112H | Missense Mutation (SNP) | VAF 41/103 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- ABCA2 | c.7038G>A p.K2346= (on ENST00000614293; = p.K2316= on NM_001606.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 58/150 reads (39%) | called by muse, mutect2, varscan2
- AMOT | c.1755G>A p.K585= (on ENST00000371959 / NM_001113490.1; = p.K176= on NM_133265.3) | Silent (SNP) | VAF 28/29 reads (97%) | catalogued as COSV59063274; called by muse, mutect2, varscan2
- BRPF1 | c.2784G>T p.V928= | Silent (SNP) | VAF 30/140 reads (21%) | called by muse, mutect2, varscan2
- CFAP58 | c.675C>G p.L225= | Silent (SNP) | VAF 3/49 reads (6%) | called by muse, mutect2
- DSG2 | c.594T>C p.Y198= | Silent (SNP) | VAF 15/192 reads (8%) | called by muse, mutect2
- EPG5 | c.6480G>A p.S2160= | Silent (SNP) | VAF 51/115 reads (44%) | catalogued as rs142224776, COSV56344288; ClinVar: likely benign; called by muse, mutect2, varscan2
- EPHB4 | c.1185G>A p.G395= | Silent (SNP) | VAF 44/158 reads (28%) | called by muse, mutect2, varscan2
- GLI1 | c.1707C>G p.S569= | Silent (SNP) | VAF 7/111 reads (6%) | called by muse, mutect2
- GUCY1A1 | c.1005T>C p.F335= | Silent (SNP) | VAF 191/298 reads (64%) | called by muse, mutect2, varscan2
- H3C8 | c.303G>A p.L101= | Silent (SNP) | VAF 128/202 reads (63%) | called by muse, mutect2, varscan2
- HELZ2 | c.6627G>A p.K2209= (on ENST00000467148 / NM_001037335.2; = p.K1640= on NM_033405.3) | Silent (SNP) | VAF 33/80 reads (41%) | catalogued as COSV101427597; called by muse, mutect2, varscan2
- HTT | c.1848C>T p.A616= | Silent (SNP) | VAF 12/126 reads (10%) | catalogued as rs762394050; called by muse, mutect2, varscan2
- IGKJ5 | c.12C>T p.F4= | Silent (SNP) | VAF 83/86 reads (97%) | catalogued as rs183927297; called by muse, mutect2, varscan2
- IGKV1-33 | c.90A>T p.P30= | Silent (SNP) | VAF 22/76 reads (29%) | catalogued as rs373610871; called by muse, varscan2
- MAP2K3 | c.453C>T p.Y151= (on ENST00000342679 / NM_145109.3; = p.Y122= on NM_002756.4) | Silent (SNP) | VAF 77/246 reads (31%) | catalogued as rs756141605; called by muse, mutect2, varscan2
- MTMR10 | c.1887G>A p.Q629= | Silent (SNP) | VAF 101/226 reads (45%) | called by muse, mutect2, varscan2
- PCDHB5 | c.1242C>T p.A414= | Silent (SNP) | VAF 24/88 reads (27%) | catalogued as COSV50650891; called by muse, mutect2, varscan2
- RADIL | c.1239G>C p.L413= | Silent (SNP) | VAF 11/103 reads (11%) | called by muse, mutect2, varscan2
- RUNDC3B | c.819A>G p.K273= | Silent (SNP) | VAF 47/176 reads (27%) | called by muse, mutect2, varscan2
- RYR1 | c.7201C>A p.R2401= | Silent (SNP) | VAF 8/31 reads (26%) | called by muse, mutect2, varscan2
- SLC5A5 | c.642C>T p.G214= | Silent (SNP) | VAF 61/150 reads (41%) | catalogued as rs542969706; called by muse, mutect2, varscan2
- SMCHD1 | c.1989T>A p.T663= | Silent (SNP) | VAF 6/114 reads (5%) | called by muse, mutect2
- SMG7 | c.376T>C p.L126= | Silent (SNP) | VAF 9/146 reads (6%) | catalogued as rs1447991784; called by muse, mutect2
- SOBP | c.870C>T p.T290= | Silent (SNP) | VAF 76/194 reads (39%) | catalogued as rs779182636, COSV100433199; called by muse, mutect2, varscan2
- TMCO4 | c.312G>A p.L104= | Silent (SNP) | VAF 35/80 reads (44%) | catalogued as rs1245956200; called by muse, mutect2, varscan2
- TXNDC2 | c.999A>T p.L333= (on ENST00000306084 / NM_001098529.2; = p.L266= on NM_032243.6) | Silent (SNP) | VAF 32/256 reads (13%) | called by muse, mutect2, varscan2
- ABCA3 | c.613+12G>A | Intron (SNP) | VAF 13/34 reads (38%) | catalogued as rs777275480; called by muse, mutect2
- ACTL10 | c.-607_-594del | 5'UTR (DEL) | VAF 31/85 reads (36%) | called by mutect2, pindel, varscan2
- ADGRL2 | c.3102-10A>C | Intron (SNP) | VAF 61/121 reads (50%) | called by muse, mutect2, varscan2
- ADH5 | c.*891A>T | 3'UTR (SNP) | VAF 13/56 reads (23%) | called by muse, mutect2, varscan2
- AFF1 | c.*2339T>C | 3'UTR (SNP) | VAF 19/65 reads (29%) | called by muse, mutect2, varscan2
- ANKRD18A | c.*486T>G | 3'UTR (SNP) | VAF 12/372 reads (3%) | called by muse, mutect2
- AP4E1 | c.*745C>A | 3'UTR (SNP) | VAF 8/134 reads (6%) | called by muse, mutect2
- ARHGAP25 | c.62-397A>T | Intron (SNP) | VAF 29/56 reads (52%) | called by muse, mutect2, varscan2
- B3GNT7 | c.*1160T>A | 3'UTR (SNP) | VAF 12/36 reads (33%) | called by muse, mutect2, varscan2
- C11orf87 | c.*3751G>A | 3'UTR (SNP) | VAF 25/66 reads (38%) | called by muse, mutect2, varscan2
- CADM2 | chr3:86067485 G>T | 3'Flank (SNP) | VAF 26/76 reads (34%) | called by muse, mutect2, varscan2
- CASP1 | c.*32+296G>T | Intron (SNP) | VAF 18/36 reads (50%) | called by muse, mutect2, varscan2
- CCDC186 | c.-210C>G | 5'UTR (SNP) | VAF 4/38 reads (11%) | catalogued as rs114530801; called by mutect2, varscan2
- CCDC32 | c.*9C>T | 3'UTR (SNP) | VAF 9/28 reads (32%) | called by muse, varscan2
- CHMP5 | c.*530G>A | 3'UTR (SNP) | VAF 12/296 reads (4%) | called by muse, mutect2
- CNOT2 | c.48+45A>G | Intron (SNP) | VAF 6/131 reads (5%) | called by muse, mutect2
- CNOT2 | c.570-233T>C | Intron (SNP) | VAF 21/66 reads (32%) | catalogued as rs1006812995; called by muse, mutect2, varscan2
- CSMD1 | c.*277G>A | 3'UTR (SNP) | VAF 64/124 reads (52%) | catalogued as rs889097426, COSV59360374; called by muse, mutect2, varscan2
- CYTH1 | c.*64A>G | 3'UTR (SNP) | VAF 38/137 reads (28%) | catalogued as rs536603148; called by muse, mutect2, varscan2
- DNM3 | c.1689+1846G>C | Intron (SNP) | VAF 12/81 reads (15%) | called by muse, mutect2, varscan2
- DYDC2 | c.*591C>G | 3'UTR (SNP) | VAF 11/26 reads (42%) | called by muse, mutect2, varscan2
- EIF5AL1 | c.*3190T>G | 3'UTR (SNP) | VAF 12/206 reads (6%) | called by muse, mutect2
- EPHB4 | c.1589-61G>A | Intron (SNP) | VAF 6/140 reads (4%) | called by muse, mutect2
- GALNT10 | c.*3939T>C | 3'UTR (SNP) | VAF 23/69 reads (33%) | called by muse, mutect2
- GPR61 | chr1:109547222 C>G | 3'Flank (SNP) | VAF 6/52 reads (12%) | called by muse, mutect2, varscan2
- HOXC13 | c.*231G>C | 3'UTR (SNP) | VAF 7/121 reads (6%) | called by muse, mutect2
- IGF2BP2 | c.240-15040C>T | Intron (SNP) | VAF 107/328 reads (33%) | called by muse, mutect2, varscan2
- IGLL5 | c.-87C>T | 5'UTR (SNP) | VAF 33/35 reads (94%) | catalogued as rs140924009; called by muse, mutect2, varscan2
- IKZF3 | c.*4221A>G | 3'UTR (SNP) | VAF 22/49 reads (45%) | called by muse, mutect2, varscan2
- IPMK | c.*3170T>G | 3'UTR (SNP) | VAF 20/45 reads (44%) | called by muse, mutect2, varscan2
- ITGA6 | chr2:172506205 G>A | 3'Flank (SNP) | VAF 36/55 reads (65%) | catalogued as rs547763978, COSV51221214; called by muse, mutect2, varscan2
- JCAD | c.*4300A>T | 3'UTR (SNP) | VAF 6/56 reads (11%) | called by muse, mutect2, varscan2
- KCNN2 | c.1255-149A>C | Intron (SNP) | VAF 7/81 reads (9%) | called by muse, mutect2
- KRT81 | c.-28_-27delinsA | 5'UTR (DEL) | VAF 86/305 reads (28%) | called by pindel, varscan2*
- LRATD1 | c.*4680A>T | 3'UTR (SNP) | VAF 15/37 reads (41%) | called by muse, mutect2, varscan2
- LRRC28 | c.168+3300C>G | Intron (SNP) | VAF 10/313 reads (3%) | catalogued as rs945816808; called by muse, mutect2
- MAD2L2 | c.-13+209C>A | Intron (SNP) | VAF 17/37 reads (46%) | called by muse, mutect2, varscan2
- MAPK9 | c.688+964A>G | Intron (SNP) | VAF 6/79 reads (8%) | called by muse, mutect2
- MARCHF8 | c.*2891T>G | 3'UTR (SNP) | VAF 54/112 reads (48%) | called by muse, mutect2, varscan2
- MFSD11 | c.96+77del | Intron (DEL) | VAF 34/131 reads (26%) | called by mutect2, pindel, varscan2
- MINDY4B | c.1240+58G>T | Intron (SNP) | VAF 79/111 reads (71%) | called by muse, mutect2, varscan2
- MON2 | chr12:62602527 C>A | 3'Flank (SNP) | VAF 54/187 reads (29%) | called by muse, mutect2, varscan2
- MYLK | c.*1419C>T | 3'UTR (SNP) | VAF 25/84 reads (30%) | called by muse, mutect2, varscan2
- NEB | c.8890-3049C>T | Intron (SNP) | VAF 43/86 reads (50%) | called by muse, mutect2, varscan2
- NKTR | c.286+560del | Intron (DEL) | VAF 43/70 reads (61%) | catalogued as COSV51772235; called by mutect2, varscan2
- NKX2-1 | c.*210_*211insTA | 3'UTR (INS) | VAF 4/34 reads (12%) | catalogued as rs1555349067, COSV61387327; called by pindel, varscan2
- NUDT21 | c.*2181T>A | 3'UTR (SNP) | VAF 42/43 reads (98%) | called by muse, mutect2, varscan2
- OR4K1 | c.*11G>A | 3'UTR (SNP) | VAF 138/649 reads (21%) | catalogued as rs767023112, COSV53462051; called by muse, mutect2, varscan2
- PLP1 | c.*713T>G | 3'UTR (SNP) | VAF 54/54 reads (100%) | called by muse, mutect2, varscan2
- POU2F1 | c.*5411A>C | 3'UTR (SNP) | VAF 31/89 reads (35%) | called by muse, mutect2, varscan2
- POU6F1 | c.847-106A>G | Intron (SNP) | VAF 10/53 reads (19%) | called by muse, varscan2
- PRDM12 | c.*108G>A | 3'UTR (SNP) | VAF 13/19 reads (68%) | called by muse, mutect2, varscan2
- PTCHD4 | c.*31T>C | 3'UTR (SNP) | VAF 50/176 reads (28%) | called by muse, mutect2, varscan2
- SHF | c.303+43G>C | Intron (SNP) | VAF 40/140 reads (29%) | called by muse, mutect2, varscan2
- SKP2 | chr5:36152081 G>C | 5'Flank (SNP) | VAF 24/266 reads (9%) | called by muse, mutect2
- SKP2 | chr5:36152082 C>T | 5'Flank (SNP) | VAF 22/264 reads (8%) | called by muse, mutect2
- SLC16A12 | c.*1196A>G | 3'UTR (SNP) | VAF 16/45 reads (36%) | called by muse, mutect2, varscan2
- SLC7A2 | c.-7C>T | 5'UTR (SNP) | VAF 100/206 reads (49%) | catalogued as rs751247329, COSV50251018; called by muse, mutect2, varscan2
- SPTLC2 | c.*2291G>C | 3'UTR (SNP) | VAF 27/63 reads (43%) | called by muse, mutect2, varscan2
- SSH2 | c.-64C>A | 5'UTR (SNP) | VAF 18/63 reads (29%) | called by muse, mutect2, varscan2
- SYT4 | c.*721A>C | 3'UTR (SNP) | VAF 27/73 reads (37%) | called by muse, mutect2, varscan2
- TBXAS1 | c.689-53C>T | Intron (SNP) | VAF 90/131 reads (69%) | called by muse, mutect2, varscan2
- TENM2 | chr5:168263834 A>G | 3'Flank (SNP) | VAF 35/93 reads (38%) | called by muse, mutect2, varscan2
- TMEM132B | c.*789G>C | 3'UTR (SNP) | VAF 15/69 reads (22%) | called by muse, mutect2, varscan2
- TRAM1L1 | c.*207T>C | 3'UTR (SNP) | VAF 8/78 reads (10%) | called by muse, mutect2
- TRPT1 | c.671-15T>G | Intron (SNP) | VAF 86/192 reads (45%) | called by muse, mutect2, varscan2
- TSPEAR | c.1566+1308G>A | Intron (SNP) | VAF 126/195 reads (65%) | catalogued as rs1431640224; called by muse, mutect2, varscan2
- VPS26C | chr21:37221231 G>C | 3'Flank (SNP) | VAF 199/307 reads (65%) | called by muse, mutect2, varscan2
